MMRF case MMRF_2239 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5acd53e7-d29a-492a-b5e4-236a1e9dc2e6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.1 years (27,083 days); ISS stage: II; Days to last known disease status: 764 days (2.1 years); Days to last follow up: 764 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 126 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 236 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -51: M Protein 1.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 28.9 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.86 µg/mL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.37 ×10⁹/L; Platelets 327 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.7 mmol/L; Albumin 40 g/L; Total Protein 8.6 g/dL; Glucose 6 mmol/L; C-Reactive Protein 0.055 mg/dL.
- Day 43 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 3.96 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.41 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 147 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 5.4 g/dL; Glucose 4.68 mmol/L.
- Day 54 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 7.25 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.78 mmol/L.
- Day 211 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 8.33 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 274 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 9.45 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.58 g/L; Beta 2 Microglobulin 3.08 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 400 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.26 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 6.01 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.88 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 5.39 mmol/L.
- Day 484 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.11 mg/dL; Immunoglobulin G 9.89 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 3.73 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 7.1 mmol/L.
- Day 589 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.76 mg/dL; Immunoglobulin G 9.95 g/L; Immunoglobulin A 1.99 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 11.7 mmol/L.
- Day 666 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.05 mg/dL; Immunoglobulin G 9.02 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.68 µg/mL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 6.77 mmol/L.
- Day 764 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.51 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.27 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6.88 mmol/L.

Other clinical attributes
- Day -51: Weight: 63 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2239_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -51 days.
- Sample MMRF_2239_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -51 days.
